Somatic mutation profile of tumor specimen TCGA-BP-5196-01A (aliquot TCGA-BP-5196-01A-01D-1429-08) from TCGA case TCGA-BP-5196, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.0 years (19,719 days).
Specimen TCGA-BP-5196-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4bc5b7d-393a-42af-9d60-9134e99d6a1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5196-11A (Solid Tissue Normal), aliquot TCGA-BP-5196-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5550f42-d478-4933-a9e3-6114f9ddf313

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 14, Frame Shift Del 5, Frame Shift Ins 4, Nonsense Mutation 3, Splice Site 3, In Frame Del 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 90/251 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs869025655, CM1410322, CM994244, COSV56545117, COSV56548828, COSV56550478, COSV56564804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMER2 | c.1549G>A p.V517I | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV63436990; called by muse, mutect2, varscan2
- ATCAY | c.360C>T p.D120= | Splice Region (SNP) | VAF 12/56 reads (21%) | catalogued as rs758678492, COSV56658098; called by muse, mutect2
- C12orf40 | c.1846C>A p.L616I | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61136441, COSV61137527, COSV61137794; called by muse, mutect2, varscan2
- CATSPERB | c.3019G>T p.A1007S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV56434815; called by muse, mutect2, varscan2
- CLK1 | c.928-1G>T p.X310_splice | Splice Site (SNP) | VAF 98/260 reads (38%) | catalogued as COSV100362440, COSV58435818; called by muse, mutect2, varscan2
- CRYBG2 | c.3586G>T p.E1196* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV57490021; called by muse, mutect2, varscan2
- DNAH9 | c.9466G>C p.A3156P | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52375628; called by muse, mutect2, varscan2
- FBN2 | c.7764T>A p.C2588* | Nonsense Mutation (SNP) | VAF 23/96 reads (24%) | catalogued as COSV52544108; called by muse, mutect2, varscan2
- GRID2 | c.1324G>C p.V442L | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV56263040, COSV99942500; called by muse, mutect2, varscan2
- KBTBD6 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.247); catalogued as COSV65271972; called by muse, mutect2, varscan2
- LRRIQ1 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV67813880; called by muse, mutect2, varscan2
- MKI67 | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.118); catalogued as COSV64076780; called by muse, mutect2, varscan2
- MYO1B | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58437654; called by muse, mutect2, varscan2
- OR4C16 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 104/368 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199938003, COSV58942583; called by muse, mutect2, varscan2
- PI4K2A | c.415T>G p.F139V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV65702258; called by muse, mutect2, varscan2
- PLEKHS1 | c.914C>A p.T305K (on ENST00000369310 / NM_182601.1; = p.T311K on NM_024889.5) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV63056770; called by muse, mutect2, varscan2
- POLR1F | c.1000A>C p.K334Q | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV55999523; called by muse, mutect2, varscan2
- PTCD3 | c.1580T>A p.L527Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54483407; called by muse, mutect2, varscan2
- RIOK3 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111330062; called by muse, mutect2
- SCAPER | c.2432T>C p.V811A | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV57753595, COSV57756064; called by muse, mutect2, varscan2
- SGPL1 | c.486+2T>C p.X162_splice | Splice Site (SNP) | VAF 18/110 reads (16%) | catalogued as COSV54737765; called by muse, mutect2, varscan2
- SH3BP4 | c.1983G>T p.L661F | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV60646354; called by muse, mutect2, varscan2
- SLC25A53 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs370922777, COSV62458774; called by muse, mutect2, varscan2
- SYTL2 | c.2356A>T p.K786* (on ENST00000528231 / NM_001162951.2; = p.K762* on NM_032943.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as COSV60363474; called by muse, mutect2, varscan2
- TRAT1 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV55469135; called by muse, mutect2, varscan2
- ZEB2 | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV57965828; called by muse, mutect2, varscan2
- ZNF155 | c.1325A>G p.N442S | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV54208393; called by muse, mutect2, varscan2
- CAMSAP2 | c.893_899del p.Q298Pfs*2 (on ENST00000236925 / NM_001297707.2; = p.Q287Pfs*2 on NM_203459.3) | Frame Shift Del (DEL) | VAF 35/193 reads (18%) | called by mutect2, pindel, varscan2
- CCDC150 | c.2825dup p.L942Ffs*9 | Frame Shift Ins (INS) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- FBXO28 | c.1049del p.K350Rfs*6 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by pindel, varscan2
- GPRIN3 | c.2087_2100del p.Y696* | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by mutect2, pindel
- IFT81 | c.1381_1382del p.T461Pfs*13 | Frame Shift Del (DEL) | VAF 31/169 reads (18%) | called by pindel, varscan2
- MYBBP1A | c.126dup p.A43Cfs*4 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- POC1B | c.569dup p.N190Kfs*6 | Frame Shift Ins (INS) | VAF 48/185 reads (26%) | called by mutect2, pindel, varscan2
- RRS1 | c.644dup p.E216Gfs*71 | Frame Shift Ins (INS) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- RUSC1 | c.758_766del p.N253_W256delinsR | In Frame Del (DEL) | VAF 36/206 reads (17%) | called by mutect2, pindel, varscan2
- SLC34A1 | c.491_493del p.S164del | In Frame Del (DEL) | VAF 33/168 reads (20%) | called by mutect2, pindel, varscan2
- SPRED1 | c.743_746del p.I248Tfs*6 | Frame Shift Del (DEL) | VAF 23/101 reads (23%) | called by mutect2, pindel*, varscan2*
- TECTA | c.2941+2dup p.X981_splice | Splice Site (INS) | VAF 25/116 reads (22%) | called by mutect2, pindel, varscan2
- CGN | c.1342C>T p.L448= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV54973504; called by muse, mutect2, varscan2
- IRF7 | c.591C>T p.L197= (on ENST00000397566; = p.L184= on NM_001572.5) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV52762348; called by muse, mutect2
- MMS19 | c.1839T>C p.P613= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV59137379; called by muse, mutect2, varscan2
- OLFM4 | c.1401A>G p.L467= | Silent (SNP) | VAF 30/178 reads (17%) | catalogued as rs1175311978, COSV54580345; called by muse, mutect2, varscan2
- PDZD2 | c.1734C>T p.L578= | Silent (SNP) | VAF 79/271 reads (29%) | catalogued as COSV56872024; called by muse, mutect2, varscan2
- PHIP | c.1920C>T p.I640= | Silent (SNP) | VAF 58/224 reads (26%) | catalogued as rs1157739223, COSV51510471; called by muse, mutect2, varscan2
- POTEF | c.2904C>T p.G968= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100665118; called by mutect2, varscan2
- PRPF6 | c.1461C>T p.I487= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs748495142, COSV53868644; called by muse, mutect2, varscan2
- RAPGEF6 | c.333G>A p.E111= | Silent (SNP) | VAF 47/230 reads (20%) | catalogued as rs750157949, COSV57255264; called by muse, mutect2, varscan2
- SLC4A1AP | c.1294T>C p.L432= | Silent (SNP) | VAF 11/316 reads (3%) | catalogued as COSV58137648; called by muse, mutect2
- SYT2 | c.1068G>A p.V356= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV66143158; called by muse, mutect2, varscan2
- WRNIP1 | c.1662G>A p.A554= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs150885902; called by muse, mutect2
- ZFHX4 | c.10119T>C p.A3373= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV50530669; called by muse, mutect2
- ZNF395 | c.1422T>C p.S474= | Silent (SNP) | VAF 52/173 reads (30%) | catalogued as COSV60430306; called by muse, mutect2, varscan2
- PGAM5 | c.719+670T>G | Intron (SNP) | VAF 45/176 reads (26%) | catalogued as COSV58202985; called by muse, mutect2, varscan2
